Somatic mutation profile of tumor specimen TCGA-EL-A3CL-01A (aliquot TCGA-EL-A3CL-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 70.5 years (25,761 days).
Specimen TCGA-EL-A3CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db2796bb-c4cc-43a3-a1cb-e720e49d2ce6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CL-10A (Blood Derived Normal), aliquot TCGA-EL-A3CL-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36729c2f-be89-441a-9998-ce1dad9a9947

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNN2 | c.906C>G p.Y302* | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV54027401; called by muse, mutect2, varscan2
- GATA5 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs202078502, COSV53345624; called by muse, mutect2
- KAT2A | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.44); catalogued as rs782345284, COSV52425309; called by muse, mutect2, varscan2
- MRPL41 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV52997269; called by muse, mutect2, varscan2
- SAMD9L | c.4689_4692del p.R1564Cfs*5 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.8960dup p.R2988Efs*33 | Frame Shift Ins (INS) | VAF 38/130 reads (29%) | called by mutect2, pindel, varscan2
- DSCAM | c.1452C>T p.C484= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV68024663; called by muse, mutect2, varscan2
- HIVEP3 | c.5718C>T p.P1906= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs141816288; called by muse, mutect2, varscan2
